Gene-level copy-number profile of tumor specimen TCGA-IG-A8O2-01A from TCGA case TCGA-IG-A8O2, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 62.6 years (22,869 days).
Specimen TCGA-IG-A8O2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.e9ff6041-4e4c-4877-b0cb-726375f0c4ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A8O2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53567de4-35f0-4051-8f37-a3cea8e66125

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 905; copy number 2: 14,701; copy number 3: 23,543; copy number 4: 17,983; copy number 5: 526; copy number 6: 1,837; copy number 7: 194; copy number 8: 27; copy number 9: 14; copy number 11: 2; copy number 13: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A8O2-01A-11D-A36I-01): tumor purity 0.64, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:96,924,620–97,140,754, 1 gene (within-gene range 0–2): KLHL32.
- chr6:109,690,609–109,878,098, 1 gene (within-gene range 0–2): FIG4.
- chr9:19,507,452–23,438,700, 77 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 244 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:49,202,126–49,451,896, 1 gene, copy number 9 (within-gene range 6–9): AC009975.2.
- chr2:49,563,388–49,888,986, 3 genes, copy number 9: AC009971.1, RPL7P13, SNORA75.
- chr2:55,547,292–55,618,880, 1 gene, copy number 7 (within-gene range 4–7): PPP4R3B.
- chr2:55,617,909–59,279,400, 30 genes, copy number 7: AC015982.2, PNPT1, EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93, PPIAP63, EIF2S2P7, AC132153.1, AC068276.1, AC073875.1, ACTG1P22, VRK2, AC068193.1, FANCL, AC007250.1, EIF3FP3, LINC01795, LINC01122, AC007238.1, AC007092.1, LINC01793.
- chr2:59,434,552–59,442,261, 1 gene, copy number 7: AC007179.1.
- chr3:85,799,987–90,257,415, 40 genes, copy number 7–9 (within-gene range 3–9): CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P.
- chr10:5,195,462–5,978,187, 31 genes, copy number 7: AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2, LASTR, AL365356.2, RN7SL445P, ASB13, TASOR2, AL365356.1, GDI2, NRBF2P5, AL596094.1, ANKRD16, RPL12P28, FBH1, AL137186.2, IL15RA.
- chr11:69,000,765–72,159,734, 106 genes, copy number 7–13 (broad region; genes not listed).
- chr12:19,129,752–19,376,400, 4 genes, copy number 7: PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P.
- chr21:15,928,296–16,645,467, 1 gene, copy number 8 (within-gene range 6–8): MIR99AHG.
- chr21:16,284,696–17,612,945, 23 genes, copy number 8 (within-gene range 5–8): SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1, NEK4P1, AP000457.1, RNU6-113P, LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3.
- chr21:18,269,116–18,486,599, 2 genes, copy number 8: TMPRSS15, AL109763.1.
- chr21:18,614,431–18,650,360, 1 gene, copy number 8 (within-gene range 3–8): AF240627.1.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
